Somatic mutation profile of tumor specimen HCM-BROD-0681-C71-02A (aliquot HCM-BROD-0681-C71-02A-01D-A83U-36) from HCMI case HCM-BROD-0681-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.2 years (18,343 days).
Specimen HCM-BROD-0681-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d2fd3ef-d655-4cfe-88d1-203b25ad6331.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0681-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0681-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89feb61f-0935-4127-b9a2-7f0a92db7a7e

The open-access MAF lists 1,181 somatic variants for this specimen: 792 protein-altering or splice-affecting, 350 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 707, Silent 350, Nonsense Mutation 37, Splice Site 28, Intron 22, Splice Region 12, Frame Shift Del 6, RNA 6, 5'Flank 4, 5'UTR 3, 3'Flank 2, 3'UTR 2.

Variants (750 of 1,181; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.853-1G>A p.X285_splice | Splice Site (SNP) | VAF 95/243 reads (39%) | catalogued as rs1085307267, CS085038, CS1513975, COSV101001390; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 10555/11200 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs565837539, CM1312225, COSV52845281; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TCF3 | c.1823-508G>A | Intron (SNP) | VAF 265/916 reads (29%) | catalogued as rs879255271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.3307A>G p.I1103V | Missense Mutation (SNP) | VAF 208/455 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.338); catalogued as rs746693787; called by muse, mutect2, varscan2
- ABI1 | c.719+1G>A p.X240_splice | Splice Site (SNP) | VAF 107/141 reads (76%) | catalogued as COSV61017743; called by muse, mutect2, varscan2
- ACAN | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 182/431 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV61370741; called by muse, mutect2, varscan2
- ACCS | c.555G>A p.G185= | Splice Region (SNP) | VAF 118/387 reads (30%) | catalogued as rs988555326; called by muse, mutect2, varscan2
- ACE | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 191/439 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs147670020; called by muse, mutect2, varscan2
- ADAM2 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV99696937; called by muse, mutect2, varscan2
- ADCY9 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 141/328 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV53576157; called by muse, mutect2, varscan2
- ADH1C | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs753685476; called by muse, mutect2, varscan2
- ADH4 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV55500245; called by muse, mutect2, varscan2
- AJAP1 | c.1164-1G>A p.X388_splice | Splice Site (SNP) | VAF 98/224 reads (44%) | catalogued as COSV65454010; called by muse, mutect2, varscan2
- ALS2 | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 139/416 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1437975145; called by muse, mutect2, varscan2
- ANKRD30B | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV62821470; called by muse, mutect2, varscan2
- ANKRD50 | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 172/425 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72385750; called by muse, mutect2, varscan2
- APH1A | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.245); catalogued as rs782134229; called by muse, mutect2, varscan2
- APOB | c.8822C>T p.T2941I | Missense Mutation (SNP) | VAF 198/454 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs768600483, COSV51936981, COSV99263491; called by muse, mutect2, varscan2
- APOH | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 110/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779872282; called by muse, mutect2, varscan2
- ARID1B | c.4462G>A p.V1488I | Missense Mutation (SNP) | VAF 280/747 reads (37%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.071); catalogued as rs768210321, COSV99268671; called by muse, mutect2, varscan2
- ASPM | c.8050G>A p.D2684N | Missense Mutation (SNP) | VAF 110/305 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV54129185; called by muse, mutect2, varscan2
- ATF7IP | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs763268952; called by muse, mutect2, varscan2
- ATM | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1445292591; called by muse, mutect2, varscan2
- ATM | c.3905G>A p.G1302D | Missense Mutation (SNP) | VAF 146/390 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as CD982455; called by muse, mutect2, varscan2
- BAHCC1 | c.5036G>A p.G1679E | Missense Mutation (SNP) | VAF 243/528 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs1555657604; called by muse, mutect2, varscan2
- BMERB1 | c.503-1G>A p.X168_splice | Splice Site (SNP) | VAF 86/328 reads (26%) | catalogued as rs113251387; called by muse, varscan2
- BOD1L1 | c.5122G>A p.D1708N | Missense Mutation (SNP) | VAF 169/440 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV50010674; called by muse, mutect2, varscan2
- BPIFB6 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 154/727 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.077); catalogued as rs775834459; called by muse, mutect2, varscan2
- BRCA2 | c.4426G>A p.D1476N | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.857); catalogued as rs1380537823, COSV66456191; called by muse, mutect2, varscan2
- BST1 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs773717822; called by muse, mutect2, varscan2
- BTBD8 | c.1769C>T p.S590L (on ENST00000636805 / NM_001376131.1; = p.S77L on NM_015237.4) | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs1195453133, COSV64885551; called by muse, mutect2, varscan2
- C2CD2L | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 99/267 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs1272428368; called by muse, mutect2, varscan2
- C2CD3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 121/308 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV100487359; called by muse, mutect2, varscan2
- CABIN1 | c.5827G>A p.V1943M | Missense Mutation (SNP) | VAF 283/940 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.365); catalogued as rs1300181578; called by muse, mutect2, varscan2
- CACNA1H | c.5665G>A p.G1889R | Missense Mutation (SNP) | VAF 271/667 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs201018826; called by muse, mutect2, varscan2
- CACNA2D1 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 57/266 reads (21%) | catalogued as rs1554385501, COSV100666950; called by muse, mutect2, varscan2
- CARMIL3 | c.3995C>T p.P1332L | Missense Mutation (SNP) | VAF 131/428 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.087); catalogued as rs1463197899; called by muse, mutect2, varscan2
- CATSPERD | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 34/210 reads (16%) | catalogued as rs1478424485; called by muse, mutect2, varscan2
- CBX3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 153/801 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as COSV61761441; called by muse, mutect2, varscan2
- CCDC60 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59547479; called by muse, mutect2, varscan2
- CCDC88C | c.3994G>A p.E1332K | Missense Mutation (SNP) | VAF 137/329 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753634468; called by muse, mutect2, varscan2
- CCDC88C | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 164/420 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs371147165; called by muse, mutect2, varscan2
- CCNE1 | c.1196G>A p.S399N | Missense Mutation (SNP) | VAF 205/831 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52904541; called by muse, mutect2, varscan2
- CDC45 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99597181; called by muse, mutect2, varscan2
- CDON | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.424); catalogued as COSV99701884; called by muse, mutect2, varscan2
- CEACAM5 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 180/666 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs782660405; called by muse, varscan2
- CEACAM8 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as rs377727534; called by muse, mutect2, varscan2
- CEP104 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 98/446 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs866682675; called by muse, mutect2, varscan2
- CHGB | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 163/614 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as rs771393741, COSV66759682, COSV66761431; called by muse, mutect2, varscan2
- CHST5 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 86/655 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs766555973, COSV100292183; called by muse, mutect2, varscan2
- CHSY3 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 131/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1227807356; called by muse, mutect2, varscan2
- COL18A1 | c.2417C>T p.P806L (on ENST00000359759 / NM_130444.3; = p.P571L on NM_030582.4) | Missense Mutation (SNP) | VAF 234/607 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.905); catalogued as rs1333056556, COSV62701076; called by muse, mutect2, varscan2
- COL20A1 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 112/740 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404257099, COSV58911434; called by muse, mutect2, varscan2
- COL6A3 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 161/407 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs865791056, COSV55084377; called by muse, mutect2, varscan2
- CPS1 | c.3953T>A p.L1318* | Nonsense Mutation (SNP) | VAF 108/325 reads (33%) | catalogued as CM120166; called by muse, mutect2, varscan2
- CROCC | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 302/1052 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs762565818, COSV65011398; called by muse, varscan2
- CSMD1 | c.8849G>A p.G2950E (on ENST00000520002; = p.G2949E on NM_033225.6) | Missense Mutation (SNP) | VAF 183/450 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59372856; called by muse, mutect2, varscan2
- CTAGE6 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 141/856 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101417803; called by muse, mutect2, varscan2
- CTR9 | c.692G>A p.C231Y | Missense Mutation (SNP) | VAF 170/409 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV63728642; called by muse, mutect2, varscan2
- DAO | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 145/369 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323058; called by muse, mutect2, varscan2
- DCC | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 158/443 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV71427379, COSV71437043; called by muse, mutect2, varscan2
- DCDC1 | c.3284G>A p.S1095N (on ENST00000597505 / NM_001367979.1; = p.S202N on NM_020869.3) | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV100338503; called by muse, mutect2, varscan2
- DCHS1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 229/590 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413559157; called by muse, mutect2, varscan2
- DDX10 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as COSV59433393; called by muse, mutect2, varscan2
- DDX60L | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 150/399 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.163); catalogued as COSV52720980; called by muse, mutect2, varscan2
- DENND3 | c.957G>A p.R319= | Splice Region (SNP) | VAF 113/299 reads (38%) | catalogued as rs1555546497; called by muse, mutect2, varscan2
- DENND4C | c.3922G>A p.E1308K (on ENST00000434457 / NM_001330640.2; = p.E1259K on NM_017925.7) | Missense Mutation (SNP) | VAF 90/126 reads (71%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as rs745779880; called by muse, mutect2, varscan2
- DGKI | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 127/415 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55956257; called by muse, mutect2, varscan2
- DHX34 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 288/936 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60895165; called by muse, mutect2, varscan2
- DNAH11 | c.6245G>A p.R2082Q | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs563280837, COSV60956774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.10195G>A p.V3399I | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs749397968, COSV54256220; ClinVar: uncertain significance; called by muse, mutect2
- DNAH9 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV52339016, COSV52345524; called by muse, mutect2, varscan2
- DNAJA4 | c.896G>A p.G299E (on ENST00000343789; = p.G328E on NM_018602.3) | Missense Mutation (SNP) | VAF 153/367 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV51217815, COSV99144553; called by muse, mutect2, varscan2
- DOCK5 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 155/393 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99376487; called by muse, mutect2, varscan2
- DSCAM | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 118/324 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as rs1252993421; called by muse, mutect2, varscan2
- DSG3 | c.2566C>T p.L856F | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771266691; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 197/498 reads (40%) | catalogued as rs770745137; called by muse, mutect2, varscan2
- EFCAB8 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.38); catalogued as rs1378666516, COSV62498721; called by muse, mutect2, varscan2
- ENO1 | c.865+1G>A p.X289_splice | Splice Site (SNP) | VAF 47/180 reads (26%) | catalogued as rs759857368; called by muse, mutect2, varscan2
- EPB41L3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 170/423 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59450932; called by muse, mutect2, varscan2
- EPHA5 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56637602; called by muse, mutect2, varscan2
- EPHB2 | c.2122G>A p.D708N (on ENST00000400191 / NM_001309193.2; = p.D709N on NM_004442.7) | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101006881; called by muse, mutect2, varscan2
- EPN1 | c.955G>A p.D319N (on ENST00000270460 / NM_001321263.1; = p.D294N on NM_013333.3) | Missense Mutation (SNP) | VAF 329/1255 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs767673424; called by muse, mutect2, varscan2
- EVC2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 128/359 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs773470850; called by muse, mutect2, varscan2
- F5 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 178/397 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV63122792; called by muse, mutect2, varscan2
- FAM181B | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 288/693 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as rs1233338330; called by muse, mutect2, varscan2
- FAM193A | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 189/510 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.943); catalogued as rs530360787; called by muse, mutect2, varscan2
- FASTKD3 | c.1919G>A p.R640K | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs760818288; called by muse, varscan2
- FBF1 | c.2020G>A p.A674T (on ENST00000586717; = p.A688T on NM_001319193.1) | Missense Mutation (SNP) | VAF 242/554 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs1398559938; called by muse, mutect2, varscan2
- FER | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99811182; called by muse, mutect2, varscan2
- FHL5 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 119/245 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100459500; called by muse, mutect2, varscan2
- FLNB | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55876013; called by muse, mutect2, varscan2
- FOS | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 210/528 reads (40%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.968); catalogued as rs1446975713; called by muse, mutect2, varscan2
- FOXB1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 182/417 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456464426, COSV101249685; called by muse, mutect2, varscan2
- FSIP2 | c.3669G>A p.W1223* | Nonsense Mutation (SNP) | VAF 148/317 reads (47%) | catalogued as COSV58101546; called by muse, mutect2, varscan2
- GAP43 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 256/559 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as COSV59348714; called by muse, mutect2, varscan2
- GATAD2B | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 111/315 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs752198126; called by muse, mutect2, varscan2
- GHRHR | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 80/359 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV58198186; called by muse, mutect2, varscan2
- GIPR | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 159/598 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1298512253, COSV54424108; called by muse, mutect2, varscan2
- GJA9 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 163/619 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100668111; called by muse, mutect2, varscan2
- GLB1L3 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.216); catalogued as COSV66280578; called by muse, mutect2, varscan2
- GLIS1 | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 258/681 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1005201769; called by muse, mutect2, varscan2
- GPR137C | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 105/278 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs768360524; called by muse, mutect2, varscan2
- GPR142 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 202/489 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as rs756897767; called by muse, mutect2, varscan2
- GRB2 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 142/374 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1430561495; called by muse, mutect2, varscan2
- GRIK2 | c.1724G>A p.S575N | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59769951; called by muse, mutect2, varscan2
- GRM3 | c.2036G>T p.R679M | Missense Mutation (SNP) | VAF 156/524 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64468213; called by muse, mutect2, varscan2
- GRM5 | c.2917G>A p.G973S (on ENST00000305447 / NM_001143831.2; = p.G941S on NM_000842.4) | Missense Mutation (SNP) | VAF 357/833 reads (43%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.02); catalogued as rs200967678; called by muse, mutect2, varscan2
- HACL1 | c.1481G>A p.W494* | Nonsense Mutation (SNP) | VAF 56/201 reads (28%) | catalogued as rs1168342042; called by muse, mutect2, varscan2
- HELZ | c.3499C>T p.P1167S | Missense Mutation (SNP) | VAF 126/485 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as rs183613778, COSV62377316; called by muse, mutect2, varscan2
- HMCN1 | c.4801C>T p.Q1601* | Nonsense Mutation (SNP) | VAF 189/493 reads (38%) | catalogued as COSV54901557; called by muse, mutect2, varscan2
- HNF4A | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 96/527 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as CM021614, CM021615, COSV57390171; called by muse, mutect2, varscan2
- HNF4A | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 133/582 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM133276; called by muse, mutect2, varscan2
- HNRNPA1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 135/327 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV52937943; called by muse, mutect2, varscan2
- HNRNPDL | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1235371971; called by muse, mutect2, varscan2
- HOMEZ | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 199/450 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100664209; called by muse, mutect2, varscan2
- HOXA6 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 27/777 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339380575, COSV56072115; called by muse, mutect2
- HOXA9 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 231/801 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58655788; called by muse, mutect2, varscan2
- HSPA13 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 126/370 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341963321; called by muse, mutect2, varscan2
- IHO1 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 24/121 reads (20%) | catalogued as rs1477749140, COSV56507696; called by muse, mutect2, varscan2
- ILDR2 | c.1211+1G>A p.X404_splice | Splice Site (SNP) | VAF 91/186 reads (49%) | catalogued as COSV54836076; called by muse, varscan2
- INAFM1 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 225/761 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1322045680; called by muse, mutect2, varscan2
- IP6K1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 137/319 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs764431758; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.292-1G>A p.X98_splice (on ENST00000485419 / NM_001197113.1; = p.X22_splice on NM_014575.3) | Splice Site (SNP) | VAF 143/333 reads (43%) | catalogued as rs1309293788; called by muse, mutect2, varscan2
- JCAD | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 193/265 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV64758055; called by muse, mutect2, varscan2
- JSRP1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 298/933 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV99677786; called by muse, mutect2, varscan2
- KASH5 | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 205/696 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs761859737; called by muse, mutect2, varscan2
- KCNA5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 38/662 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV99363856; called by muse, mutect2
- KCNQ2 | c.2194C>T p.P732S (on ENST00000359125 / NM_172107.4; = p.P704S on NM_004518.6) | Missense Mutation (SNP) | VAF 410/1834 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs749597397; called by muse, mutect2, varscan2
- KDM3A | c.2932G>A p.V978M | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1458921571; called by muse, mutect2, varscan2
- KDM5D | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 243/563 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100522190; called by muse, mutect2, varscan2
- KIAA1549 | c.3988G>A p.D1330N | Missense Mutation (SNP) | VAF 195/653 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs533057424; called by muse, mutect2, varscan2
- KIF19 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 351/864 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs775255824; called by muse, mutect2, varscan2
- KIF24 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 117/156 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934573071, COSV61454777; called by muse, mutect2, varscan2
- KLF9 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772506798, COSV101009616; called by muse, mutect2, varscan2
- KMT2C | c.5167G>A p.D1723N | Missense Mutation (SNP) | VAF 172/605 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs200338679; called by muse, mutect2, varscan2
- KRT15 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 229/597 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.072); catalogued as rs555279126; called by muse, mutect2, varscan2
- KRTAP10-9 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 209/543 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59966798; called by muse, mutect2, varscan2
- LHX6 | c.221G>A p.G74D (on ENST00000373755 / NM_001242334.2; = p.G103D on NM_014368.5) | Missense Mutation (SNP) | VAF 108/410 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV61343990; called by muse, varscan2
- LILRB5 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 232/882 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100300748; called by muse, mutect2, varscan2
- LMO7 | c.2344G>A p.V782I (on ENST00000357063; = p.V463I on NM_005358.5) | Missense Mutation (SNP) | VAF 81/123 reads (66%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1399921006, COSV58552359; called by muse, mutect2, varscan2
- LPA | c.3794C>T p.T1265M | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs752058838; called by muse, mutect2, varscan2
- LRCH4 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 234/986 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.091); catalogued as rs1416011438; called by muse, mutect2, varscan2
- LRRC14B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 231/524 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as rs552867607; called by muse, mutect2, varscan2
- LRRC2 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs776257045; called by muse, mutect2, varscan2
- LRRC56 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 73/305 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs895854243; called by muse, mutect2, varscan2
- LTBP2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 317/831 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.058); catalogued as rs553562104, COSV56213477; called by muse, mutect2, varscan2
- LY75 | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs1308176006; called by muse, mutect2, varscan2
- LZTS3 | c.1301G>A p.R434Q (on ENST00000329152; = p.R388Q on NM_001282533.2) | Missense Mutation (SNP) | VAF 179/650 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs1332163331, COSV100232085, COSV61278145; called by muse, mutect2, varscan2
- MAML1 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 182/483 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99483591; called by muse, varscan2
- MAN2A1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 122/321 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54851612; called by muse, mutect2, varscan2
- MAP1S | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 295/1049 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418134241; called by muse, mutect2, varscan2
- MARK1 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV65067232; called by muse, mutect2, varscan2
- MC3R | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 141/502 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99710806; called by muse, mutect2, varscan2
- MCC | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 208/468 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as rs748327549; called by muse, mutect2, varscan2
- METTL14 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66310759; called by muse, mutect2, varscan2
- METTL26 | c.488+1G>A p.X163_splice | Splice Site (SNP) | VAF 177/422 reads (42%) | catalogued as rs199799134; called by muse, mutect2, varscan2
- MINDY4 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54672992; called by muse, mutect2, varscan2
- MKRN3 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 262/642 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs1487520973, COSV58811273; called by muse, mutect2, varscan2
- MLLT1 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 263/879 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53132483; called by muse, mutect2, varscan2
- MMP15 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 182/450 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as rs745919855; called by muse, mutect2, varscan2
- MORC1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99226086; called by muse, mutect2, varscan2
- MS4A14 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 122/310 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1378929378; called by muse, mutect2, varscan2
- MUC16 | c.19567C>T p.P6523S | Missense Mutation (SNP) | VAF 118/408 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV67501710; called by muse, mutect2, varscan2
- MUC16 | c.18697C>T p.P6233S | Missense Mutation (SNP) | VAF 151/530 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs376365857; called by muse, mutect2, varscan2
- MUC16 | c.13430C>T p.S4477F | Missense Mutation (SNP) | VAF 204/619 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs1353871237; called by muse, mutect2, varscan2
- MUC16 | c.12833C>T p.S4278F | Missense Mutation (SNP) | VAF 134/503 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs1323347445, COSV67469508; called by muse, varscan2
- MUC6 | c.2390C>A p.A797D | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1564841610; called by muse, mutect2, varscan2
- MXRA5 | c.5692C>T p.P1898S | Missense Mutation (SNP) | VAF 106/129 reads (82%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV99476118; called by muse, mutect2, varscan2
- NBAS | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs1250190572; called by muse, mutect2, varscan2
- NCOA7 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs768462504; called by muse, mutect2, varscan2
- NDUFA13 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 166/624 reads (27%) | catalogued as COSV99389202; called by muse, mutect2, varscan2
- NDUFV2 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as rs770259847, COSV100571730; called by muse, mutect2, varscan2
- NEK11 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1280450371; called by muse, mutect2, varscan2
- NFE2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 110/287 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV56456438; called by muse, mutect2, varscan2
- NIPBL | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 207/473 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV99241184; called by muse, mutect2, varscan2
- NPIPB5 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 84/565 reads (15%) | SIFT tolerated, low confidence (0.09); catalogued as rs750310002; called by muse, mutect2, varscan2
- NRP1 | c.1505G>A p.G502D | Missense Mutation (SNP) | VAF 194/260 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99588258; called by muse, mutect2, varscan2
- NSMF | c.751G>A p.E251K (on ENST00000371475 / NM_001130969.3; = p.E249K on NM_015537.4) | Missense Mutation (SNP) | VAF 113/425 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs150552443; called by muse, mutect2, varscan2
- NT5DC2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58733833; called by muse, mutect2, varscan2
- NTNG1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 171/458 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99639882; called by muse, mutect2, varscan2
- NUP98 | c.3499G>A p.E1167K (on ENST00000359171 / NM_001365126.1; = p.E1150K on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/475 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.397); catalogued as rs775968781; called by muse, mutect2, varscan2
- OLR1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 181/427 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs753070166; called by muse, mutect2, varscan2
- OR2M5 | c.569A>T p.N190I | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV63547196; called by muse, mutect2, varscan2
- OR3A1 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 234/599 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs372102685; called by muse, mutect2
- OR4D10 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 165/406 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs764383479; called by muse, mutect2, varscan2
- OR4M1 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 123/266 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100270967; called by muse, varscan2
- OR51B2 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs772461820; called by muse, mutect2, varscan2
- OR52D1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 175/424 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781665830; called by muse, mutect2, varscan2
- OR5B17 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62160827; called by muse, mutect2, varscan2
- OR5B2 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs369296397; called by muse, mutect2, varscan2
- OR7A10 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 98/401 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764338523, COSV50166447; called by muse, mutect2, varscan2
- OR8B12 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 181/442 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1336257012; called by muse, mutect2, varscan2
- PABPC1L | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 144/537 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99407931; called by muse, mutect2, varscan2
- PADI1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 181/443 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64937988; called by muse, mutect2, varscan2
- PADI3 | c.1904C>T p.T635I | Missense Mutation (SNP) | VAF 154/402 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.122); catalogued as rs767108956; called by muse, mutect2, varscan2
- PAM | c.2720G>A p.G907E (on ENST00000438793 / NM_001319943.1; = p.G908E on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs543056414; called by muse, mutect2, varscan2
- PATJ | c.4247G>A p.G1416D | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56247974; called by muse, mutect2, varscan2
- PAX4 | c.645+1G>A p.X215_splice | Splice Site (SNP) | VAF 137/529 reads (26%) | catalogued as COSV100490191; called by muse, mutect2, varscan2
- PCBP2 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 69/187 reads (37%) | catalogued as COSV100827422, COSV63729265; called by muse, mutect2, varscan2
- PDE10A | c.2286G>A p.W762* | Nonsense Mutation (SNP) | VAF 104/289 reads (36%) | catalogued as COSV63092303, COSV63098680; called by muse, mutect2, varscan2
- PDE4D | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 316/760 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1480373658; called by muse, mutect2, varscan2
- PDE6B | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs373925141; called by muse, mutect2, varscan2
- PECR | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54734593; called by muse, mutect2, varscan2
- PGM5 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 113/666 reads (17%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.875); catalogued as rs782483282; called by muse, mutect2, varscan2
- PHIP | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51503561; called by muse, mutect2, varscan2
- PIBF1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 70/99 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58319746; called by muse, mutect2, varscan2
- PLA2G4F | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 139/370 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs143229349; called by muse, mutect2, varscan2
- PLEKHM2 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 259/921 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.092); catalogued as rs751121316; called by muse, mutect2, varscan2
- PLOD2 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 108/288 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV51461966; called by muse, mutect2, varscan2
- PLS1 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 126/318 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61832936; called by muse, mutect2, varscan2
- PNPLA7 | c.2144C>T p.T715M | Missense Mutation (SNP) | VAF 232/602 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1192704454, COSV52999448; called by muse, mutect2, varscan2
- PPP1R9A | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 133/524 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195714; called by muse, mutect2, varscan2
- PRAMEF17 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 73/193 reads (38%) | catalogued as COSV65816231; called by muse, mutect2, varscan2
- PRKG2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 194/474 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52319078; called by muse, mutect2, varscan2
- PSMC2 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53006678; called by muse, mutect2, varscan2
- PTGES3 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV56273548; called by muse, mutect2, varscan2
- RAI1 | c.3119G>A p.G1040E | Missense Mutation (SNP) | VAF 274/644 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.84); catalogued as rs775150135; called by muse, mutect2, varscan2
- RAI1 | c.3218G>A p.G1073D | Missense Mutation (SNP) | VAF 239/618 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as rs1419475241; called by muse, mutect2, varscan2
- RAX | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 267/699 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1178316569; called by muse, mutect2, varscan2
- RBM34 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs370629801; called by muse, mutect2, varscan2
- RC3H2 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.785); catalogued as rs200582531; called by muse, mutect2, varscan2
- RDH12 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs754373553; called by muse, mutect2, varscan2
- RHOQ | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 66/105 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53190153, COSV99475865; called by muse, mutect2, varscan2
- RINL | c.857C>T p.A286V (on ENST00000591812 / NM_001195833.2; = p.A172V on NM_198445.4) | Missense Mutation (SNP) | VAF 243/890 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs201138591; called by muse, mutect2, varscan2
- RNF123 | c.2311G>A p.G771S | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.769); catalogued as rs868494915; called by muse, mutect2, varscan2
- RNF208 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 198/714 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs765677313; called by muse, mutect2, varscan2
- ROBO4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 199/496 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as rs762765651, COSV60621735; called by muse, mutect2, varscan2
- RPIA | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 160/447 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52171757, COSV99376570; called by muse, mutect2, varscan2
- RSAD2 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 140/372 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV101150022; called by muse, varscan2
- SACS | c.11375G>A p.R3792Q | Missense Mutation (SNP) | VAF 151/204 reads (74%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.799); catalogued as rs778633704; called by muse, mutect2, varscan2
- SAG | c.513G>A p.K171= | Splice Region (SNP) | VAF 121/158 reads (77%) | catalogued as COSV68590773; called by muse, mutect2, varscan2
- SAMD9 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 110/525 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.355); catalogued as rs775712957; called by muse, mutect2, varscan2
- SCAF1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 164/615 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs761751484; called by muse, mutect2, varscan2
- SDK1 | c.5599C>T p.R1867W | Missense Mutation (SNP) | VAF 215/753 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142107345; called by muse, mutect2, varscan2
- SEC14L1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66725796; called by muse, mutect2, varscan2
- SELENOO | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 108/148 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1318849054; called by muse, mutect2, varscan2
- SERPINC1 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 136/397 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM113675; called by muse, mutect2, varscan2
- SFRP4 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 169/617 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV71412370; called by muse, mutect2, varscan2
- SGPP2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138702204, COSV58330549; called by muse, mutect2, varscan2
- SGPP2 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 178/436 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs1192472260; called by muse, mutect2, varscan2
- SIGLEC12 | c.959C>T p.T320I (on ENST00000291707 / NM_053003.4; = p.T202I on NM_033329.2) | Missense Mutation (SNP) | VAF 219/851 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.727); catalogued as rs769143281; called by muse, mutect2, varscan2
- SIGLEC6 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 210/721 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1158191358; called by muse, mutect2, varscan2
- SLA2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 203/690 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs200208007; called by muse, mutect2, varscan2
- SLC16A14 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 256/662 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99725857; called by muse, mutect2, varscan2
- SLC17A7 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 119/453 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55550614; called by muse, mutect2, varscan2
- SLC22A14 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 200/507 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99828291; called by muse, mutect2, varscan2
- SLC2A10 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 213/738 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763372108; called by muse, varscan2
- SLC3A1 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 93/116 reads (80%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs199678349; called by muse, mutect2, varscan2
- SLC47A1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs1176534699, COSV99565405; called by muse, mutect2, varscan2
- SLC4A5 | c.1025+1G>A p.X342_splice | Splice Site (SNP) | VAF 149/340 reads (44%) | catalogued as rs1558880876; called by muse, mutect2, varscan2
- SLC6A20 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 151/344 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs775225439, COSV62071062; called by muse, mutect2, varscan2
- SLFN12 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 128/335 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs764941956, COSV59226778; called by muse, mutect2, varscan2
- SLMAP | c.1321G>A p.V441M (on ENST00000428312 / NM_001377924.1; = p.V462M on NM_007159.5) | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs1368014490; called by muse, mutect2, varscan2
- SNED1 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 216/504 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs958567301; called by muse, mutect2, varscan2
- SNRPA | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 178/616 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as rs1158032963; called by muse, mutect2, varscan2
- SOCS2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 103/267 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292602320; called by muse, mutect2, varscan2
- SPEF2 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61551974; called by muse, mutect2, varscan2
- SPPL2A | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 131/366 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs781566248; called by muse, mutect2, varscan2
- SPTA1 | c.5692G>A p.E1898K | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63758463, COSV63762100; called by muse, mutect2, varscan2
- SSBP1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 113/456 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV99519850; called by muse, mutect2, varscan2
- STK3 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1563702776; called by muse, mutect2, varscan2
- SUGCT | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751540603, COSV59330454; called by muse, mutect2, varscan2
- SV2A | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 216/521 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.018); catalogued as rs782641312; called by muse, mutect2, varscan2
- SVEP1 | c.6988G>A p.E2330K | Missense Mutation (SNP) | VAF 163/374 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754419975; called by muse, mutect2, varscan2
- SYCP1 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1427841221; called by muse, mutect2, varscan2
- SYNE2 | c.10016del p.K3339Rfs*5 | Frame Shift Del (DEL) | VAF 99/313 reads (32%) | catalogued as COSV59974984; called by mutect2, pindel, varscan2
- SYT17 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs1475095681; called by muse, mutect2, varscan2
- TBL3 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 59/601 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as rs1054597441; called by muse, mutect2
- TDO2 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs762745653; called by muse, mutect2, varscan2
- TF | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 206/503 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV99396527; called by muse, mutect2, varscan2
- THAP12 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 152/342 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.383); catalogued as rs989114523, COSV52612663; called by muse, mutect2, varscan2
- TIAM1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 211/485 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV54537099; called by muse, mutect2, varscan2
- TIAM2 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 162/363 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1562328671; called by muse, mutect2, varscan2
- TMEM126B | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs139974357; called by muse, mutect2, varscan2
- TMEM132C | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 283/637 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100175058; called by muse, mutect2, varscan2
- TMEM132D | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 199/452 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67163019; called by muse, mutect2, varscan2
- TMEM170B | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101053260; called by muse, mutect2, varscan2
- TMEM207 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 140/413 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1414625440; called by muse, mutect2, varscan2
- TMEM71 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 98/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs551754127, COSV63457486, COSV63459280; called by muse, mutect2, varscan2
- TMEM87B | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1221567422; called by muse, mutect2, varscan2
- TNN | c.3590C>T p.T1197M | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750138050; called by muse, mutect2, varscan2
- TP53BP1 | c.3800G>A p.R1267K | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55511722; called by muse, mutect2, varscan2
- TPX2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs775408777; called by muse, varscan2
- TRANK1 | c.2882G>A p.G961D | Missense Mutation (SNP) | VAF 186/460 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV57143181; called by muse, mutect2, varscan2
- TRAPPC9 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 141/468 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV66909558; called by muse, mutect2, varscan2
- TRIM58 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1380221051; called by muse, mutect2, varscan2
- TRIO | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 125/333 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.223); catalogued as rs1031853907; called by muse, mutect2, varscan2
- TTN | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 135/380 reads (36%) | PolyPhen probably damaging (0.996); catalogued as rs747867752, COSV59862739; called by muse, mutect2, varscan2
- TUBG1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 187/671 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as rs1203383045; called by muse, mutect2, varscan2
- TXNDC5 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 222/515 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1331817479; called by muse, mutect2, varscan2
- UBR2 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65751946; called by muse, mutect2, varscan2
- UGT2A1 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 117/350 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763710867; called by muse, mutect2, varscan2
- UNC13D | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 117/317 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs962992811; called by muse, mutect2, varscan2
- UNC5C | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 161/422 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs200667278; called by muse, mutect2, varscan2
- UNC80 | c.4201G>T p.D1401Y | Missense Mutation (SNP) | VAF 38/553 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99072509; called by muse, mutect2
- USH1C | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs267602805, COSV50014069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP44 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51562781; called by muse, mutect2, varscan2
- USP6 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs1567787859; called by muse, mutect2, varscan2
- VPS28 | c.39C>T p.A13= | Splice Region (SNP) | VAF 104/251 reads (41%) | catalogued as rs1257554712, COSV99034920; called by muse, mutect2, varscan2
- VPS51 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 35/594 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1442045175; called by muse, mutect2
- WDFY4 | c.8509G>A p.V2837M | Missense Mutation (SNP) | VAF 33/383 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.206); catalogued as rs1156261245; called by muse, mutect2
- WDR75 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 141/332 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1336635084; called by muse, mutect2, varscan2
- XIRP2 | c.7141G>A p.E2381K (on ENST00000628543; = p.E2556K on NM_152381.6) | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs145874680, COSV54701233, COSV54707403; called by muse, mutect2, varscan2
- ZBTB1 | c.1996G>A p.V666I | Missense Mutation (SNP) | VAF 164/396 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as rs1387954698; called by muse, mutect2, varscan2
- ZBTB10 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 229/622 reads (37%) | catalogued as COSV66946738; called by muse, mutect2, varscan2
- ZEB2 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV57951239; called by muse, mutect2, varscan2
- ZFP30 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as COSV63623015; called by muse, mutect2, varscan2
- ZNF521 | c.3929G>A p.S1310N | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.258); catalogued as rs1426103422; called by mutect2, varscan2
- ZNF560 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV56872547; called by muse, mutect2, varscan2
- ZNF92 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.4); catalogued as COSV60872950; called by muse, varscan2
- ZSWIM6 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 168/428 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs747444881; called by muse, mutect2, varscan2
- AACS | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 164/362 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- ABCB9 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 213/517 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ABHD17A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 315/1002 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ACE | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ADAM29 | c.1078A>G p.N360D | Missense Mutation (SNP) | VAF 152/402 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ADAMTS6 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 132/386 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ADCY3 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 154/420 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ADCY4 | c.2783G>A p.G928D | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADGB | c.3074C>T p.T1025I | Missense Mutation (SNP) | VAF 118/317 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ADGRB3 | c.3349G>A p.V1117I | Missense Mutation (SNP) | VAF 161/406 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- ADGRD1 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 120/291 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ADGRV1 | c.2687G>A p.G896D | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADM | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 236/599 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADRB3 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 194/586 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- AGBL2 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AGBL5 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 131/320 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- AGGF1 | c.1634-1G>A p.X545_splice | Splice Site (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- AIFM3 | c.465G>A p.Q155= | Splice Region (SNP) | VAF 153/420 reads (36%) | called by muse, mutect2, varscan2
- ALCAM | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 158/395 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOX15B | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 134/384 reads (35%) | called by muse, mutect2, varscan2
- ANAPC7 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 186/434 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ARAP1 | c.3532G>A p.V1178M (on ENST00000393609 / NM_001040118.2; = p.V933M on NM_015242.4) | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ARF5 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 82/331 reads (25%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 42/525 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- ARHGAP44 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 97/268 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ARHGEF5 | c.2321G>A p.G774D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); called by mutect2, varscan2
- ATG2B | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 121/284 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BBC3 | c.371C>A p.P124H (on ENST00000449228 / NM_001127240.3; = p.P90T on NM_014417.5) | Missense Mutation (SNP) | VAF 167/595 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- BICRA | c.4480G>A p.D1494N | Missense Mutation (SNP) | VAF 284/1112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMF | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 133/388 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPTF | c.5383G>A p.G1795R | Missense Mutation (SNP) | VAF 175/387 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- BRMS1L | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- BRPF3 | c.2765G>A p.G922D | Missense Mutation (SNP) | VAF 183/501 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- BTBD3 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 150/606 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- BUD13 | c.272T>A p.V91E | Missense Mutation (SNP) | VAF 153/578 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- C16orf95 | c.464C>T p.P155L (on ENST00000253461 / NM_001195125.2; = p.P216= on NM_001195124.3) | Missense Mutation (SNP) | VAF 209/528 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C20orf173 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 272/912 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- C2CD4C | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 351/1153 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- C5orf22 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- CAMSAP1 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CAMSAP2 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 132/327 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAMSAP3 | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 190/650 reads (29%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.3221C>T p.S1074F | Missense Mutation (SNP) | VAF 144/566 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CANX | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CATSPER3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 120/342 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CBX8 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 147/337 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC151 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 240/870 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CCDC177 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 228/564 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC88B | c.2952G>C p.E984D | Missense Mutation (SNP) | VAF 148/416 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CCNB2 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCZ1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CD300LB | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 136/329 reads (41%) | called by muse, mutect2, varscan2
- CDCA7 | c.346G>A p.E116K (on ENST00000347703 / NM_145810.3; = p.E195K on NM_031942.5) | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CDCP1 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 156/353 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CDHR3 | c.1482C>A p.S494R | Missense Mutation (SNP) | VAF 141/707 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEACAM3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 87/312 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR3 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 290/687 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP290 | c.2991+1G>A p.X997_splice | Splice Site (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- CEP43 | c.103-1G>A p.X35_splice | Splice Site (SNP) | VAF 95/261 reads (36%) | called by muse, mutect2, varscan2
- CEP68 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 201/557 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CFAP43 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 146/169 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAF1A | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 259/977 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CIT | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 137/353 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- CLCNKA | c.577-1G>A p.X193_splice | Splice Site (SNP) | VAF 196/648 reads (30%) | called by muse, mutect2, varscan2
- CLEC9A | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 131/386 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLIC6 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 246/686 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLNK | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 137/349 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CLTCL1 | c.3562G>A p.D1188N | Missense Mutation (SNP) | VAF 150/437 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- CMIP | c.2122G>A p.E708K (on ENST00000537098 / NM_198390.2; = p.E614K on NM_030629.3) | Missense Mutation (SNP) | VAF 190/446 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CMTR1 | c.1821G>A p.G607= | Splice Region (SNP) | VAF 120/256 reads (47%) | called by muse, mutect2, varscan2
- CNTN6 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COBLL1 | c.230C>T p.S77F (on ENST00000392717; = p.S39F on NM_014900.5) | Missense Mutation (SNP) | VAF 192/480 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- COL2A1 | c.2294G>A p.G765D | Missense Mutation (SNP) | VAF 126/299 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A3 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 123/321 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPHXL | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 180/400 reads (45%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- CPSF6 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 188/494 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CTAGE8 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 69/610 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CTNNBL1 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 95/371 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CTRB2 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DAAM2 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 197/488 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DACT1 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 228/526 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DCAF8 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DDX52 | c.859+1G>A p.X287_splice | Splice Site (SNP) | VAF 121/291 reads (42%) | called by muse, mutect2, varscan2
- DDX60 | c.3443C>T p.T1148I | Missense Mutation (SNP) | VAF 111/342 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DENND2C | c.1387G>A p.A463T (on ENST00000393274 / NM_001256404.2; = p.A406T on NM_198459.4) | Missense Mutation (SNP) | VAF 116/317 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DEPDC5 | c.2720G>A p.G907D (on ENST00000400246; = p.G976D on NM_014662.5) | Missense Mutation (SNP) | VAF 242/570 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIAPH3 | c.2290C>T p.Q764* (on ENST00000400324 / NM_001042517.2; = p.Q501* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 104/142 reads (73%) | called by muse, mutect2, varscan2
- DIP2B | c.3148G>A p.V1050M | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DMPK | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 243/867 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH14 | c.9232C>T p.H3078Y (on ENST00000445597; = p.H4086Y on NM_001367479.1) | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.11818G>A p.D3940N | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DOCK4 | c.4846C>T p.P1616S | Missense Mutation (SNP) | VAF 115/384 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DOK3 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 357/794 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOP1B | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 149/350 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DPYS | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 175/490 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRD2 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 269/732 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- DSC2 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- DSCAML1 | c.6233C>T p.T2078I (on ENST00000321322; = p.T2018I on NM_020693.4) | Missense Mutation (SNP) | VAF 163/412 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- DSG1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 129/348 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DST | c.1986+1G>A p.X662_splice (on ENST00000361203 / NM_001374722.1; = p.X336_splice on NM_001723.6) | Splice Site (SNP) | VAF 63/160 reads (39%) | called by muse, mutect2, varscan2
- DTNA | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 127/350 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DYNC2LI1 | c.126G>A p.G42= | Splice Region (SNP) | VAF 89/115 reads (77%) | called by muse, mutect2, varscan2
- E2F3 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 157/410 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ECM2 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EFCAB14 | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 172/495 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- EFNB2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 260/354 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- EGR4 | c.1127del p.P376Rfs*4 (on ENST00000545030; = p.P273Rfs*4 on NM_001965.4) | Frame Shift Del (DEL) | VAF 252/720 reads (35%) | called by mutect2, pindel, varscan2
- EGR4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 445/960 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EHBP1L1 | c.3970C>T p.P1324S | Missense Mutation (SNP) | VAF 226/560 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- EHMT1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 192/547 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF3H | c.684_686del p.H228_E229delinsQ | In Frame Del (DEL) | VAF 142/346 reads (41%) | called by mutect2, pindel, varscan2
- EML5 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- EML6 | c.2933G>A p.G978E | Missense Mutation (SNP) | VAF 89/286 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ENG | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 49/664 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.22); called by muse, mutect2
- ENTR1 | c.848G>A p.R283K (on ENST00000357365 / NM_001039707.2; = p.R260K on NM_006643.4) | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- EP400 | c.9058C>T p.P3020S | Missense Mutation (SNP) | VAF 131/370 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- EPHB6 | c.2366G>A p.S789N | Missense Mutation (SNP) | VAF 357/1168 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EPYC | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERICH5 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 206/506 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ESPL1 | c.3307G>A p.G1103S | Missense Mutation (SNP) | VAF 211/510 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ESPN | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 106/769 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EVI5L | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 142/506 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- EXOC3L1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 140/539 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC4 | c.2564G>A p.G855D | Missense Mutation (SNP) | VAF 139/554 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- EXPH5 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- FAM117A | c.1202G>A p.C401Y | Missense Mutation (SNP) | VAF 242/613 reads (39%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FAN1 | c.2561G>A p.G854E | Missense Mutation (SNP) | VAF 133/360 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FAT2 | c.7435C>T p.P2479S | Missense Mutation (SNP) | VAF 189/460 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXL17 | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 304/743 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); called by muse, varscan2
- FBXO31 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 348/748 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL5 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 124/275 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- FGF5 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 177/432 reads (41%) | called by muse, mutect2, varscan2
- FGGY | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FLG | c.10280C>T p.S3427F | Missense Mutation (SNP) | VAF 172/468 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLG2 | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 183/457 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- FLNB | c.2264G>A p.S755N | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- FN3KRP | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FPR3 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 186/640 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FRMD1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FRMD6 | c.749G>A p.G250E (on ENST00000344768 / NM_001267046.2; = p.G242E on NM_152330.4) | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRYL | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FSIP2 | c.9991G>A p.E3331K | Missense Mutation (SNP) | VAF 149/367 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUNDC2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 181/215 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- GAD1 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- GALNT14 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT5 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 128/350 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAN | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 148/408 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GAS8 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 147/315 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- GBP5 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GCN1 | c.4951T>G p.L1651V | Missense Mutation (SNP) | VAF 131/308 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GDPD2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 199/242 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GJA5 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 208/506 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLI1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 144/437 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GNS | c.795C>T p.N265= | Splice Region (SNP) | VAF 55/167 reads (33%) | called by muse, mutect2, varscan2
- GOLGA6L6 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 49/326 reads (15%) | called by muse, mutect2, varscan2
- GOLGB1 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 118/294 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GOT1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 119/181 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR137C | c.629G>A p.S210N | Missense Mutation (SNP) | VAF 152/409 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- GTF2I | c.2597G>A p.R866K (on ENST00000573035 / NM_032999.4; = p.R825K on NM_001518.5) | Missense Mutation (SNP) | VAF 66/457 reads (14%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- HAS2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 134/344 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAUS1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEATR3 | c.1640G>A p.G547D | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- HEATR5B | c.4397C>T p.P1466L | Missense Mutation (SNP) | VAF 167/217 reads (77%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HEG1 | c.3517+1G>A p.X1173_splice | Splice Site (SNP) | VAF 119/287 reads (41%) | called by muse, mutect2, varscan2
- HIVEP1 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 163/360 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- HLA-E | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HMX1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 355/850 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPF | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 169/222 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- HSD17B3 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 152/472 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSF4 | c.751G>T p.G251C (on ENST00000521374 / NM_001040667.3; = p.W255C on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/485 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSP90AB1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 133/384 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSP90AB1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 129/365 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HSPG2 | c.2195+1G>A p.X732_splice | Splice Site (SNP) | VAF 151/358 reads (42%) | called by muse, mutect2, varscan2
- HTR3D | c.1150G>T p.E384* (on ENST00000382489 / NM_001163646.2; = p.E209* on NM_182537.3) | Nonsense Mutation (SNP) | VAF 138/376 reads (37%) | called by muse, mutect2, varscan2
- HUWE1 | c.7168C>T p.L2390F | Missense Mutation (SNP) | VAF 187/226 reads (83%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- IARS1 | c.2792G>A p.G931E | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ICAM4 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 193/693 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- IDE | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 201/253 reads (79%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IFT52 | c.768G>A p.E256= | Splice Region (SNP) | VAF 23/473 reads (5%) | called by muse, mutect2
- IGHV3-35 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 129/346 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV3-49 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 129/344 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- IGLV4-3 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 170/604 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- IGSF9B | c.4295G>A p.G1432E | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- IL4R | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 28/636 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.086); called by muse, mutect2
- IMPG1 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2
- INCENP | c.2202G>A p.E734= (on ENST00000394818 / NM_001040694.2; = p.E730= on NM_020238.3) | Splice Region (SNP) | VAF 222/524 reads (42%) | called by muse, mutect2, varscan2
- INF2 | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IPO8 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IPO8 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 140/332 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IQGAP2 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 143/348 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ITCH | c.1447G>A p.G483S (on ENST00000262650 / NM_001257137.3; = p.G442S on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/363 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ITGA2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2
- ITK | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 165/424 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2896C>T p.H966Y | Missense Mutation (SNP) | VAF 224/541 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KATNIP | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 155/435 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KCNG1 | c.1188_1198del p.Y396* | Nonsense Mutation (DEL) | VAF 210/770 reads (27%) | called by mutect2, pindel, varscan2
- KCNH7 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 163/404 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIF21A | c.4319G>A p.S1440N (on ENST00000361418 / NM_001378440.1; = p.S1427N on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/275 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KMT2C | c.1813+1G>A p.X605_splice | Splice Site (SNP) | VAF 75/305 reads (25%) | called by muse, mutect2, varscan2
- KRT14 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KTN1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 135/343 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- KTN1 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- LAMA1 | c.3657G>A p.W1219* | Nonsense Mutation (SNP) | VAF 167/420 reads (40%) | called by muse, mutect2, varscan2
- LDLRAD2 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 57/526 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- LEPR | c.1536G>A p.W512* | Nonsense Mutation (SNP) | VAF 147/386 reads (38%) | called by muse, mutect2, varscan2
- LILRB1 | c.1786G>A p.E596K (on ENST00000427581; = p.E546K on NM_006669.6) | Missense Mutation (SNP) | VAF 168/637 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LINC00514 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 158/356 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.05); called by muse, varscan2
- LMNB1 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- LMNB1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LNX1 | c.1892+1G>A p.X631_splice (on ENST00000263925 / NM_001126328.3; = p.X535_splice on NM_032622.2) | Splice Site (SNP) | VAF 128/295 reads (43%) | called by muse, mutect2, varscan2
- LRP1B | c.10843G>T p.G3615* | Nonsense Mutation (SNP) | VAF 53/184 reads (29%) | called by muse, mutect2, varscan2
- LRRC37A2 | c.3973C>T p.P1325S | Missense Mutation (SNP) | VAF 247/1261 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRRC7 | c.355C>T p.L119F (on ENST00000651989 / NM_001370785.2; = p.L86F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRN1 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 172/391 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LTA4H | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 136/349 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY6L | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 145/377 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LYST | c.6842G>A p.G2281D | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MAGEC1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 237/266 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MAGEC1 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 174/219 reads (79%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- MAGEE2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 180/218 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MAN2B1 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 353/1200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K3 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K7 | c.1495G>A p.A499T (on ENST00000369329 / NM_145331.3; = p.A472T on NM_003188.4) | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAPRE1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MED23 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 125/317 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MED24 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 287/618 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- MEGF8 | c.6887G>A p.G2296D (on ENST00000251268 / NM_001271938.2; = p.G2229D on NM_001410.3) | Missense Mutation (SNP) | VAF 164/543 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MFSD12 | c.621C>A p.D207E | Missense Mutation (SNP) | VAF 268/960 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MGAT5B | c.2300C>T p.S767F (on ENST00000569840 / NM_001199172.2; = p.S765F on NM_144677.3) | Missense Mutation (SNP) | VAF 268/659 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MIER3 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- MKRN1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 142/566 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MLLT6 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- MMP16 | c.16T>A p.F6I | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MNT | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 306/674 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); called by muse, mutect2
- MPRIP | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MSH4 | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTCH1 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 136/373 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MTERF3 | c.677+1G>A p.X226_splice | Splice Site (SNP) | VAF 84/198 reads (42%) | called by muse, mutect2, varscan2
- MTMR12 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- MTPAP | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 84/116 reads (72%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MUC16 | c.12815C>T p.T4272I | Missense Mutation (SNP) | VAF 153/539 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); called by muse, varscan2
- MUC17 | c.2240C>G p.T747S | Missense Mutation (SNP) | VAF 136/580 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2
- MUC2 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYEOV | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 217/519 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- MYH2 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MYL12A | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 148/362 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MYLK2 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 158/589 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MYO1B | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MYOF | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 97/132 reads (73%) | called by muse, mutect2, varscan2
- NARS2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NBPF26 | c.2705A>C p.Y902S (on ENST00000620612; = p.Y640S on NM_001351372.1) | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- NCL | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 161/437 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- NDUFA1 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 110/125 reads (88%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NEO1 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NFATC3 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 176/470 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- NFE2L2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 196/491 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NFE2L3 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 376/1170 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NHLRC2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 166/223 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKAIN4 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 64/1178 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- NLN | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- NLRC3 | c.3028C>A p.Q1010K | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NLRP2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NOP53 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 113/430 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NUP205 | c.4990G>A p.D1664N | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- OGFR | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 144/501 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OMD | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 172/404 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- OOSP4B | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 116/294 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10K1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 174/397 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11H6 | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 89/234 reads (38%) | called by muse, mutect2, varscan2
- OR4D11 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 180/407 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- OR51A2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 143/230 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, varscan2
- OR5T1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD7A | c.826G>A p.E276K (on ENST00000307050 / NM_001382637.1; = p.E269K on NM_130901.3) | Missense Mutation (SNP) | VAF 201/548 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OVOL2 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 350/1277 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PAFAH1B1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 120/334 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK3 | c.991G>A p.V331I (on ENST00000262836 / NM_001324328.2; = p.V316I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PARP1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- PARP2 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 166/453 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PATJ | c.3577G>A p.G1193R | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PCARE | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 149/409 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDHA6 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 180/383 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PCDHGA8 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 138/346 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PCDHGC5 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 229/614 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCED1B | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 309/716 reads (43%) | called by muse, mutect2, varscan2
- PDHA2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 202/476 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- PDS5A | c.3526C>T p.P1176S | Missense Mutation (SNP) | VAF 129/310 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PER1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 165/426 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PGK2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGR | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 393/936 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PGRMC2 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PIGG | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3C3 | c.1386_1389del p.E464Ffs*15 | Frame Shift Del (DEL) | VAF 81/316 reads (26%) | called by mutect2, pindel, varscan2
- PKD1 | c.12289G>A p.G4097S (on ENST00000262304 / NM_001009944.3; = p.G4096S on NM_000296.4) | Missense Mutation (SNP) | VAF 311/707 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PKHD1L1 | c.8414-1G>A p.X2805_splice | Splice Site (SNP) | VAF 88/186 reads (47%) | called by muse, mutect2, varscan2
- PLK1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 45/393 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- PLXNA1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 202/469 reads (43%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 224/530 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, varscan2
- PNPLA6 | c.2632G>A p.G878S (on ENST00000414982 / NM_001166111.2; = p.G830S on NM_006702.5) | Missense Mutation (SNP) | VAF 197/689 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLH | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 121/312 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- POSTN | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 134/165 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPDPF | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 333/1440 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PPFIA2 | c.2171C>T p.T724I | Missense Mutation (SNP) | VAF 131/376 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PPFIA2 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PPFIA3 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 128/503 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PRKCSH | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 218/844 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROM1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 182/453 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PROM1 | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- PSMA5 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 127/315 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTAR1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 160/369 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PTPN11 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 179/471 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PTPRQ | c.1259C>T p.T420I (on ENST00000616559; = p.T378I on NM_001145026.2) | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRS | c.5536G>A p.E1846K | Missense Mutation (SNP) | VAF 170/716 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PWWP3B | c.90del p.R31Gfs*7 | Frame Shift Del (DEL) | VAF 164/264 reads (62%) | called by mutect2, pindel, varscan2
- PYCR1 | c.659C>A p.S220* | Nonsense Mutation (SNP) | VAF 203/507 reads (40%) | called by muse, mutect2, varscan2
- QRSL1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 127/331 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- QTRT1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 245/890 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB28 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- RAPGEF2 | c.371-1G>A p.X124_splice | Splice Site (SNP) | VAF 86/186 reads (46%) | called by muse, mutect2, varscan2
- RBBP6 | c.3475G>A p.D1159N | Missense Mutation (SNP) | VAF 153/369 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RBM26 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 175/250 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- RBPJ | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 131/290 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCC1 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCN1 | c.836A>T p.D279V | Missense Mutation (SNP) | VAF 104/283 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- REV3L | c.6061A>G p.K2021E | Missense Mutation (SNP) | VAF 154/363 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RFPL4AL1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 94/846 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RFPL4AL1 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, varscan2
- RFPL4AL1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); called by muse, varscan2
- RGS12 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 241/545 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RGS20 | c.685C>T p.Q229* (on ENST00000297313 / NM_170587.4; = p.Q82* on NM_003702.4) | Nonsense Mutation (SNP) | VAF 105/152 reads (69%) | called by muse, mutect2, varscan2
- RGS3 | c.2368C>T p.P790S (on ENST00000350696 / NM_001282923.2; = p.P509S on NM_130795.4) | Missense Mutation (SNP) | VAF 80/725 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- RIF1 | c.2792G>A p.S931N | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- RIMBP3 | c.4801G>A p.D1601N | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RIMBP3 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RMND5A | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RNASEH1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 180/423 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF217 | c.1148G>A p.C383Y (on ENST00000521654 / NM_001286398.2; = p.C91Y on NM_152553.5) | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RNF43 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 141/401 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ROBO2 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 115/334 reads (34%) | called by muse, mutect2, varscan2
- ROCK1 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 159/388 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL23A | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- RPUSD2 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 204/474 reads (43%) | called by muse, mutect2, varscan2
- RRM1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RSBN1 | c.1976G>A p.R659K | Missense Mutation (SNP) | VAF 118/342 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SAFB2 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 172/644 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SASS6 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 99/132 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAF1 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 294/1124 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- SEC16A | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 144/565 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SEC16A | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 152/360 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- SEL1L2 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 122/530 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SEMA3C | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 109/419 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SEMA3F | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 174/391 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SGCB | c.753+1G>A p.X251_splice | Splice Site (SNP) | VAF 96/217 reads (44%) | called by muse, mutect2, varscan2
- SH2D4B | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 153/188 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SHISA6 | c.1477G>A p.A493T (on ENST00000409168 / NM_001173461.1; = p.A544T on NM_207386.4) | Missense Mutation (SNP) | VAF 176/415 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SIGIRR | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 117/330 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SIGLEC9 | c.1107-1G>A p.X369_splice | Splice Site (SNP) | VAF 61/271 reads (23%) | called by muse, mutect2, varscan2
- SLC19A3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 214/464 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC1A2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 198/428 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC1A4 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 403/935 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A5 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 114/142 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLC26A3 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 105/441 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SLC30A5 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SLC34A1 | c.1175-1G>A p.X392_splice | Splice Site (SNP) | VAF 110/270 reads (41%) | called by muse, mutect2, varscan2
- SLC41A1 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 245/599 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A9 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 142/356 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SMC6 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 119/319 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMG6 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 177/440 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMG8 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 191/493 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SMIM13 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 199/510 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SMOX | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 189/676 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SNED1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 229/624 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SNRPB2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SNRPC | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 145/412 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SNTA1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 105/358 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SNX19 | c.2068A>G p.T690A | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SNX27 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX18 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 254/1310 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SOX9 | c.801del p.I268Sfs*11 | Frame Shift Del (DEL) | VAF 254/684 reads (37%) | called by mutect2, pindel, varscan2
- SP1 | c.2063G>A p.C688Y (on ENST00000327443 / NM_138473.3; = p.C681Y on NM_003109.1) | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPAM1 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 117/481 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA16 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 121/337 reads (36%) | called by muse, mutect2, varscan2
- SPATA21 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 168/701 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA5L1 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 149/356 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SPEG | c.6241G>A p.D2081N | Missense Mutation (SNP) | VAF 388/865 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SPHK2 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 319/1008 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPTBN4 | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 176/633 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- SPTLC1 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SRMS | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 291/1220 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, varscan2
- ST6GALNAC1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 212/552 reads (38%) | PolyPhen benign (0); called by muse, mutect2
- ST7L | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ST8SIA1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 174/388 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STARD6 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- STK32B | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.058); called by muse, mutect2
- STN1 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- STRC | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 251/1108 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- STX19 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 142/322 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUGCT | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUSD4 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 147/404 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SYCP2 | c.2716G>A p.V906I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYNE2 | c.7435G>A p.E2479K | Missense Mutation (SNP) | VAF 139/429 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNPO | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 248/620 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SYT10 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- TAAR2 | c.1025C>T p.T342I (on ENST00000367931 / NM_001033080.1; = p.T297I on NM_014626.3) | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, varscan2
- TAB2 | c.1619A>G p.Q540R | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TACC3 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 104/609 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBX3 | c.1750C>T p.Q584* (on ENST00000257566 / NM_016569.4; = p.Q564* on NM_005996.4) | Nonsense Mutation (SNP) | VAF 220/576 reads (38%) | called by muse, mutect2, varscan2
- TCEA2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 80/492 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); called by muse, varscan2
- TCOF1 | c.1612G>A p.V538M (on ENST00000377797 / NM_001135243.1; = p.V461M on NM_000356.4) | Missense Mutation (SNP) | VAF 260/652 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TEAD3 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 249/620 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TENM2 | c.3265C>T p.Q1089* (on ENST00000518659 / NM_001122679.2; = p.Q857* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 205/484 reads (42%) | called by muse, mutect2, varscan2
- TGFBR3L | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 307/1042 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TLR5 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 127/375 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TM2D1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TMEM147 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 183/673 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMEM39B | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 122/335 reads (36%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMPRSS11E | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 160/416 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFRSF10A | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- TNFSF9 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 392/1201 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TPR | c.5776G>A p.D1926N | Missense Mutation (SNP) | VAF 130/369 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TPX2 | c.1153A>G p.S385G | Missense Mutation (SNP) | VAF 175/603 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TRBJ2-6 | c.3C>T p.*1= | Missense Mutation (SNP) | VAF 303/1016 reads (30%) | called by muse, mutect2, varscan2
- TRIB3 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 249/958 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRPV4 | c.2030C>T p.T677I | Missense Mutation (SNP) | VAF 230/574 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TSC22D2 | c.1643G>A p.S548N | Missense Mutation (SNP) | VAF 272/642 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TTF1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TTN | c.78730G>A p.E26244K (on ENST00000591111; = p.E18820K on NM_003319.4) | Missense Mutation (SNP) | VAF 139/311 reads (45%) | PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TTN | c.61198C>T p.P20400S (on ENST00000591111; = p.P12976S on NM_003319.4) | Missense Mutation (SNP) | VAF 129/326 reads (40%) | PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TUBA3D | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 110/370 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- TXNDC11 | c.1358C>T p.T453I (on ENST00000356957 / NM_001303447.2; = p.T426I on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 226/583 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- UBE3A | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 192/466 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- UBR1 | c.1850G>A p.G617D | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UROS | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 105/155 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USB1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 171/460 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- USH2A | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 158/381 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USP25 | c.2011A>G p.T671A | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- USP26 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 191/232 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.408); called by muse, mutect2, varscan2
431 further variants in this file (43 protein-altering or splice-affecting, 350 silent, 38 other) are not listed here.
